Somatic mutation profile of tumor specimen TCGA-DK-A3IT-01A (aliquot TCGA-DK-A3IT-01A-31D-A20D-08) from TCGA case TCGA-DK-A3IT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 62.4 years (22,786 days).
Specimen TCGA-DK-A3IT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94d5ec81-cabf-454d-8760-530574d15569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IT-10A (Blood Derived Normal), aliquot TCGA-DK-A3IT-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0f15bfe-82d8-42ca-a2cb-c2fbd0329891

The open-access MAF lists 453 somatic variants for this specimen: 362 protein-altering or splice-affecting, 77 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 311, Silent 77, Nonsense Mutation 40, 5'Flank 8, Splice Region 4, Splice Site 3, Frame Shift Del 2, 3'Flank 2, Intron 2, Translation Start Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM131 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2, varscan2
- ABCC9 | c.4638G>A p.M1546I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53968903, COSV53988054, COSV99687607; called by muse, mutect2, varscan2
- ACP3 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60485616; called by muse, mutect2, varscan2
- ADAMTS9 | c.2643G>T p.W881C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55779540; called by muse, mutect2, varscan2
- ADAT1 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV57185698; called by muse, mutect2, varscan2
- ADIPOR1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV100579497, COSV61851379; called by muse, mutect2
- AL662899.2 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as COSV63263740; called by muse, mutect2, varscan2
- AMIGO3 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs755736042, COSV57538294; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7034C>G p.S2345C | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV51845423; called by muse, mutect2, varscan2
- ANKRD16 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV51947262; called by mutect2, varscan2
- ANPEP | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55590987; called by muse, mutect2, varscan2
- APOBR | c.2362G>A p.E788K (on ENST00000431282; = p.E797K on NM_018690.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60490101; called by muse, mutect2, varscan2
- ARAP1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771187419; called by muse, mutect2
- ARFGAP1 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62262852; called by muse, mutect2, varscan2
- ASPRV1 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57227903; called by muse, mutect2, varscan2
- ASPRV1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV57227908; called by muse, varscan2
- ASPRV1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV57227919; called by muse, varscan2
- ATP12A | c.2161C>A p.Q721K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54514977; called by muse, mutect2, varscan2
- ATP8B1 | c.1597G>C p.V533L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52175024; called by muse, varscan2
- ATP8B1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV52175036; called by muse, varscan2
- B4GALNT3 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV56751763; called by muse, mutect2, varscan2
- BARHL2 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.068); catalogued as COSV64981170; called by muse, mutect2, varscan2
- BBS9 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV54165133; called by muse, mutect2, varscan2
- BCLAF3 | c.1383G>C p.Q461H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61413727; called by muse, mutect2, varscan2
- BPIFA2 | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53610851; called by muse, mutect2, varscan2
- BRAP | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58155823; called by muse, varscan2
- BRINP3 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV66521097; called by muse, mutect2, varscan2
- BRWD1 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60894777; called by muse, mutect2, varscan2
- BSN | c.4162C>A p.P1388T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV56516455; called by muse, mutect2, varscan2
- BTBD2 | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV55308473; called by muse, mutect2, varscan2
- C2CD3 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV58092425; called by muse, varscan2
- CACNA1G | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV61725019; called by muse, mutect2, varscan2
- CAP1 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV61223681; called by muse, mutect2, varscan2
- CAPG | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99809424; called by muse, mutect2, varscan2
- CASP5 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828125; called by muse, mutect2, varscan2
- CBL | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV50634930; called by muse, mutect2, varscan2
- CC2D1B | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.469); catalogued as COSV52559907; called by muse, mutect2, varscan2
- CCDC120 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100896665; called by muse, mutect2, varscan2
- CCDC171 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52640074; called by muse, mutect2, varscan2
- CCT5 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV54723620; called by muse, mutect2, varscan2
- CD300LF | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56896705; called by muse, mutect2
- CD7 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV53939064; called by muse, mutect2, varscan2
- CD8A | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.083); catalogued as rs1173569177, COSV52157069, COSV52158530; called by muse, mutect2, varscan2
- CDCA5 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs765678897, COSV51869207; called by muse, mutect2, varscan2
- CDH23 | c.2872A>G p.I958V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1462924115, COSV54931345; called by muse, mutect2, varscan2
- CDK3 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as COSV56909913; called by muse, mutect2, varscan2
- CDKL1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV53579134; called by muse, mutect2, varscan2
- CELSR3 | c.9925G>T p.E3309* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV99374576; called by muse, mutect2, varscan2
- CELSR3 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV50849832; called by muse, mutect2, varscan2
- CEP63 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as rs1553789251, COSV59675765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS6 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV59829098, COSV59835837; called by muse, mutect2, varscan2
- CHD2 | c.4769C>G p.S1590C | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV101244632, COSV67708334; called by muse, mutect2, varscan2
- CHIT1 | c.365C>G p.S122W | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146544, COSV55148280; called by muse, mutect2, varscan2
- CHKB | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as CM1511809, COSV56417316; called by muse, mutect2, varscan2
- CLASP1 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs755481967, COSV55321664; called by muse, mutect2, varscan2
- CLCF1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.996); catalogued as COSV56861550; called by muse, mutect2, varscan2
- CLYBL | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59220454, COSV59221314; called by muse, mutect2, varscan2
- CMTM2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51748468; called by muse, mutect2, varscan2
- COL17A1 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV62226411, COSV62226774; called by muse, mutect2, varscan2
- COL2A1 | c.2463G>A p.P821= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as rs769766820, COSV61529827; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV52110091, COSV52111311; called by muse, mutect2, varscan2
- CREB5 | c.154G>C p.D52H (on ENST00000357727 / NM_182898.4; = p.D45H on NM_004904.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63219939, COSV63228462; called by muse, mutect2, varscan2
- CSRNP3 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58777694; called by muse, mutect2, varscan2
- CUEDC1 | c.792G>T p.L264F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV64226328; called by muse, mutect2, varscan2
- CUX1 | c.1732G>C p.D578H (on ENST00000437600 / NM_181500.4; = p.D580H on NM_001913.5) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52928707; called by muse, mutect2, varscan2
- DACH1 | c.1879-1G>A p.X627_splice (on ENST00000619232 / NM_001366712.1; = p.X373_splice on NM_004392.6) | Splice Site (SNP) | VAF 33/165 reads (20%) | catalogued as COSV57496948; called by muse, mutect2, varscan2
- DAG1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV58183698; called by muse, mutect2, varscan2
- DCP1B | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs1462909593, COSV54968526; called by muse, mutect2, varscan2
- DDR1 | c.2014G>C p.E672Q (on ENST00000324771; = p.E635Q on NM_001954.4) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61320750, COSV61326391; called by muse, mutect2, varscan2
- DENND6A | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60768362; called by muse, mutect2, varscan2
- DIDO1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56619920; called by muse, mutect2, varscan2
- DMXL2 | c.7435G>A p.E2479K | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51844692; called by muse, mutect2, varscan2
- DNAJC16 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65448435; called by muse, mutect2, varscan2
- DNAJC16 | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV65448439; called by muse, mutect2, varscan2
- DNMT1 | c.541C>G p.Q181E | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61577320, COSV61578606; called by muse, mutect2, varscan2
- DNMT1 | c.508C>G p.H170D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.091); catalogued as COSV61578616; called by muse, mutect2, varscan2
- DOK2 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as rs373240046; called by muse, mutect2, varscan2
- DOP1B | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV67693046; called by muse, mutect2
- DSCAML1 | c.5515G>C p.E1839Q (on ENST00000321322; = p.E1779Q on NM_020693.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58388721; called by muse, mutect2, varscan2
- EDC4 | c.3995G>C p.R1332P | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59302520; called by muse, mutect2, varscan2
- EED | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV54559014; called by muse, mutect2, varscan2
- EFHB | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs142916632; called by muse, mutect2, varscan2
- EIF2AK1 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV52238524; called by muse, mutect2, varscan2
- EIF4E3 | c.417G>C p.W139C (on ENST00000425534 / NM_001134651.2; = p.W33C on NM_173359.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55203816; called by muse, mutect2
- EIF5B | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56812455; called by muse, mutect2, varscan2
- EIF5B | c.2430G>C p.E810D | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV56812462; called by muse, varscan2
- EIF5B | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56812466; called by muse, mutect2, varscan2
- EML3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs1159368425, COSV53882112; called by muse, mutect2, varscan2
- ERICH3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV58604811; called by muse, mutect2, varscan2
- FAN1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62950426; called by muse, mutect2, varscan2
- FANCA | c.3791C>A p.S1264Y | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57067566; called by muse, mutect2, varscan2
- FBH1 | c.84C>A p.F28L (on ENST00000362091 / NM_178150.3; = p.F79L on NM_032807.4) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62982322, COSV62983061; called by muse, mutect2, varscan2
- FETUB | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV54005383, COSV54006487; called by muse, mutect2, varscan2
- FOXC2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs751774927, CD098486, COSV57444109; called by muse, mutect2, varscan2
- GAD1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV60152118; called by muse, mutect2, varscan2
- GANAB | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100648153, COSV60466060; called by muse, varscan2
- GCLM | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64686972; called by muse, mutect2, varscan2
- GDPD4 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV60018827; called by muse, mutect2
- GLDC | c.2610C>G p.F870L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.061); catalogued as COSV58679095; called by muse, mutect2, varscan2
- GLG1 | c.1897C>G p.P633A | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52666159; called by muse, varscan2
- GMFB | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs373310072, COSV63737659; called by muse, mutect2, varscan2
- GMPPB | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV57538296; called by muse, mutect2
- GNB1L | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV61548344; called by muse, mutect2, varscan2
- GPLD1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV57756279; called by muse, mutect2, varscan2
- GPR68 | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176190; called by muse, mutect2, varscan2
- GREB1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs370262420, COSV52185136; called by muse, mutect2, varscan2
- GRIN1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.861); catalogued as rs1183383915, COSV59292823; called by muse, mutect2, varscan2
- GRIN1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as COSV59293643; called by muse, mutect2, varscan2
- H1-2 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV59189887, COSV59190473; called by muse, mutect2, varscan2
- H1-6 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58090390; called by muse, mutect2, varscan2
- H2AC11 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV60361987; called by muse, mutect2, varscan2
- H2AC15 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); catalogued as rs761136744, COSV100356896, COSV57585526; called by muse, mutect2, varscan2
- H3-3B | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54665901, COSV54665976; called by muse, mutect2, varscan2
- HCFC1 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60071564; called by muse, mutect2, varscan2
- HCST | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV52887562, COSV52888644; called by muse, mutect2
- HEATR6 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV51745022; called by muse, mutect2, varscan2
- HLCS | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51767802; called by muse, mutect2, varscan2
- HORMAD1 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV59270865; called by muse, mutect2, varscan2
- HRC | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV53255998; called by muse, mutect2
- HSCB | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV53261855, COSV53262260, COSV53262443; called by muse, mutect2, varscan2
- HSF1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV68821083; called by muse, mutect2
- HSP90AA1 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV53488328; called by muse, mutect2, varscan2
- IBTK | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs774178754, COSV104402461, COSV60391935; called by muse, mutect2, varscan2
- IGDCC4 | c.2802C>G p.F934L | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV61536384; called by muse, mutect2, varscan2
- IGDCC4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61535278; called by muse, mutect2, varscan2
- INF2 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs1227037613, COSV53031920; called by muse, mutect2, varscan2
- INTS5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs761969399, COSV57951245; called by muse, mutect2, varscan2
- INTS7 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV65344136; called by muse, mutect2, varscan2
- IRAK4 | c.1003G>C p.A335P | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV71210384; called by muse, mutect2, varscan2
- IRF2BP1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs201096414, COSV56193361; called by muse, mutect2, varscan2
- ITGA4 | c.1658G>C p.R553T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV51999544, COSV52002738; called by muse, mutect2, varscan2
- KCND2 | c.1529A>G p.N510S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.012); catalogued as COSV58577014; called by muse, mutect2, varscan2
- KCNN3 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.897); catalogued as COSV55215470; called by muse, mutect2, varscan2
- KCNT1 | c.716G>A p.R239H (on ENST00000488444; = p.R258H on NM_020822.3) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1172086515, COSV53699969; called by muse, mutect2, varscan2
- KIAA0586 | c.138G>C p.L46F (on ENST00000619416 / NM_001244190.2; = p.L61F on NM_014749.5) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as COSV53621484; called by muse, mutect2, varscan2
- KIF3B | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65227413; called by muse, mutect2, varscan2
- KIF3C | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53098903; called by muse, varscan2
- KIFAP3 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV63033115, COSV63033763; called by muse, mutect2, varscan2
- KLHDC8B | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60411688; called by muse, mutect2, varscan2
- KMT2C | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV51430922; called by muse, mutect2
- KMT2D | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV99981796; called by muse, mutect2
- KNTC1 | c.5612C>T p.S1871L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV61079777; called by muse, mutect2, varscan2
- KRTAP12-4 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59959224; called by muse, mutect2, varscan2
- LCTL | c.1135C>A p.L379M | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV57179416; called by muse, mutect2, varscan2
- LHX4 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV55373399, COSV55374823; called by muse, mutect2, varscan2
- LPAR3 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as COSV65453329; called by muse, mutect2, varscan2
- LRP10 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV62078111; called by muse, mutect2, varscan2
- LRP6 | c.1600C>A p.H534N | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53786339; called by muse, mutect2, varscan2
- LRRC57 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs186716946, COSV52999855; called by muse, mutect2, varscan2
- LRRC8D | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV61578736; called by muse, mutect2, varscan2
- LRRIQ1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV67829506; called by muse, mutect2, varscan2
- MAGEB1 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV66775629; called by muse, mutect2, varscan2
- MAP3K4 | c.4008G>C p.L1336F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV62332637; called by muse, mutect2, varscan2
- MCRIP2 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53468741; called by muse, mutect2, varscan2
- MED24 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as COSV62418235; called by muse, mutect2, varscan2
- MEGF10 | c.2103A>G p.Q701= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57248146; called by muse, mutect2, varscan2
- MEIS1 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 119/445 reads (27%) | catalogued as COSV55486970; called by muse, mutect2, varscan2
- MLLT10 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56994548; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2263C>G p.R755G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64055260; called by muse, mutect2, varscan2
- MPP6 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037463; called by muse, mutect2, varscan2
- MPZL2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV54048628; called by muse, mutect2, varscan2
- MRPL41 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV52997737; called by muse, varscan2
- MSLN | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs989324901, COSV53501398, COSV53501610; called by muse, mutect2, varscan2
- MST1R | c.3883G>C p.D1295H | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56567924, COSV99619528; called by muse, mutect2, varscan2
- MSTN | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs761832176, COSV53620798; called by muse, varscan2
- MSTN | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV53620824; called by muse, mutect2, varscan2
- MSTN | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as rs1182619306, COSV53620835; called by muse, mutect2, varscan2
- MTF1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs984280990, COSV65988839; called by muse, mutect2, varscan2
- MUC16 | c.24576G>C p.M8192I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.02); catalogued as COSV67457969, COSV67461104, COSV67461268; called by muse, mutect2, varscan2
- MUC17 | c.4663C>G p.P1555A | Missense Mutation (SNP) | VAF 84/596 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV60286271, COSV60295345; called by muse, mutect2, varscan2
- MUC17 | c.5171C>G p.S1724C | Missense Mutation (SNP) | VAF 93/695 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60285014, COSV60286278; called by muse, mutect2, varscan2
- MUC6 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV70139895; called by muse, mutect2, varscan2
- MYB | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57197722; called by muse, mutect2, varscan2
- MYB | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV57197744; called by muse, mutect2, varscan2
- MYH3 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56863701; called by muse, mutect2, varscan2
- MYH6 | c.3954A>C p.K1318N | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62449626; called by muse, mutect2, varscan2
- MYH7 | c.3232G>C p.E1078Q | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV62518477; called by muse, mutect2, varscan2
- N6AMT1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV58134236; called by muse, mutect2, varscan2
- NAALAD2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58960377; called by muse, mutect2, varscan2
- NARS2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs544657093, COSV55251162, COSV99028674; called by muse, mutect2, varscan2
- NBPF10 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV100744026; called by muse, mutect2
- NES | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs752976655, COSV63960814; called by muse, mutect2
- NFE2L2 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as COSV67960927; called by muse, mutect2, varscan2
- NFRKB | c.37G>C p.E13Q (on ENST00000446488 / NM_001143835.2; = p.E26Q on NM_006165.3) | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs1490113559, COSV58757599; called by muse, mutect2, varscan2
- NIBAN2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1273088198, COSV55939606; called by muse, mutect2, varscan2
- NOP16 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV51257547, COSV99220849; called by muse, mutect2, varscan2
- NPAT | c.1529C>G p.T510S | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53717642; called by muse, mutect2, varscan2
- NR1D1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV52842294; called by muse, mutect2, varscan2
- NR1D2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs770012545, COSV56991542; called by muse, varscan2
- NR1D2 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV56991549; called by muse, varscan2
- NSDHL | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV64743701; called by muse, mutect2, varscan2
- NT5DC3 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV67321633; called by muse, mutect2, varscan2
- NUP210 | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54405385; called by mutect2, varscan2
- NUTM1 | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV61546787, COSV61547405; called by muse, mutect2, varscan2
- OGA | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV63381497; called by muse, mutect2, varscan2
- OPN5 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV55245148; called by muse, mutect2, varscan2
- OR2A25 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.376); catalogued as COSV68717089; called by muse, mutect2, varscan2
- OR2L13 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV63551658, COSV63551939; called by muse, mutect2, varscan2
- PALD1 | c.2265G>A p.A755= | Splice Region (SNP) | VAF 37/105 reads (35%) | catalogued as rs200907930, COSV54972504; called by muse, mutect2, varscan2
- PALLD | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV54978776, COSV54980826; called by muse, mutect2
- PAQR6 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764417629, COSV52744925; called by muse, mutect2, varscan2
- PARP3 | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV51753946; called by muse, varscan2
- PCDH12 | c.2550C>G p.F850L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV51520880; called by muse, mutect2, varscan2
- PCDH12 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51520893; called by muse, mutect2, varscan2
- PCDH8 | c.2827C>G p.H943D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV58812176; called by muse, mutect2, varscan2
- PCDHGA10 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs759873920, COSV53932814; called by muse, mutect2, varscan2
- PEBP4 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56465816; called by muse, mutect2, varscan2
- PEX1 | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50397142; called by muse, mutect2, varscan2
- PHF3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs368685403; called by muse, mutect2, varscan2
- PHLDB2 | c.3250G>A p.E1084K (on ENST00000393925 / NM_001134439.2; = p.E1041K on NM_145753.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1453211323, COSV101208696; called by muse, mutect2
- PIK3C2G | c.2902C>T p.R968C (on ENST00000676171; = p.R927C on NM_004570.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368805708; called by muse, mutect2, varscan2
- PIWIL4 | c.514-1G>A p.X172_splice | Splice Site (SNP) | VAF 82/283 reads (29%) | catalogued as COSV54408986; called by muse, mutect2, varscan2
- PLEC | c.4825G>A p.E1609K (on ENST00000322810 / NM_201380.4; = p.E1499K on NM_000445.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs1554702969, COSV59627490; called by muse, mutect2, varscan2
- PLEKHA8 | c.1230-1G>C p.X410_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV51650410; called by muse, mutect2, varscan2
- PLEKHG5 | c.571G>C p.E191Q (on ENST00000400915 / NM_001042663.3; = p.E154Q on NM_020631.6) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV61701436; called by muse, mutect2, varscan2
- PLIN3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.692); catalogued as rs202240827, COSV55734960; called by muse, mutect2, varscan2
- PLPP1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53304583; called by muse, mutect2, varscan2
- PLPP1 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53304603, COSV99301895; called by muse, mutect2, varscan2
- PPP1R35 | c.571C>G p.R191G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1346943810, COSV52768685; called by muse, mutect2, varscan2
- PPP2R5E | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs950547340, COSV61741436, COSV61743885; called by muse, mutect2, varscan2
- PPRC1 | c.3959G>C p.R1320P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53384707, COSV53386731; called by muse, mutect2, varscan2
- PPRC1 | c.4592G>C p.R1531T | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53384713; called by muse, mutect2, varscan2
- PPRC1 | c.4872G>C p.K1624N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV53384725; called by muse, mutect2, varscan2
- PRUNE1 | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV54957936; called by muse, mutect2, varscan2
- PSME4 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as COSV66364589; called by muse, mutect2, varscan2
- PTK7 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV57848090; called by muse, mutect2, varscan2
- PTPN13 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100364329, COSV57406135; called by muse, mutect2, varscan2
- PTPRB | c.3376C>G p.L1126V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV54238804; called by muse, mutect2, varscan2
- PUF60 | c.1187C>T p.S396L (on ENST00000526683 / NM_001362896.2; = p.S379L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57582887; called by muse, mutect2, varscan2
- QRICH1 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV62615226; called by muse, mutect2, varscan2
- RABGGTA | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53769932; called by muse, mutect2, varscan2
- RASL11B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50535001; called by muse, mutect2, varscan2
- RBPMS2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV55604210; called by muse, mutect2, varscan2
- RELCH | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56884190, COSV99902004; called by muse, mutect2, varscan2
- REN | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs115181548, COSV65817650; called by muse, mutect2, varscan2
- RETREG3 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs751254427, COSV53816905; called by muse, mutect2, varscan2
- RFWD3 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV63097660; called by muse, mutect2, varscan2
- RIN2 | c.2354A>G p.Y785C (on ENST00000255006 / NM_001242581.1; = p.Y736C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54787160; called by muse, mutect2, varscan2
- RTL9 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs148619359, COSV101511787, COSV71825504; called by muse, mutect2, varscan2
- RXRG | c.1320C>G p.F440L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV63231954; called by muse, mutect2, varscan2
- RYR2 | c.7241G>C p.G2414A | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63672323, COSV63680255; called by muse, mutect2, varscan2
- SALL2 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as rs935161796; called by muse, mutect2, varscan2
- SAMD7 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as rs778339771, COSV100156950; called by muse, mutect2, varscan2
- SEC14L3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV53178895; called by muse, mutect2, varscan2
- SERPINH1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63997929; called by muse, mutect2, varscan2
- SETDB1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54979770, COSV54984186; called by muse, mutect2, varscan2
- SF3B2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs1242365241, COSV59427119; called by muse, mutect2, varscan2
- SLC14A2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769220365, COSV54908308; called by muse, mutect2, varscan2
- SLC23A3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs1005515798, COSV55406498; called by muse, mutect2, varscan2
- SLC24A2 | c.1599G>C p.E533D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53863062; called by muse, mutect2, varscan2
- SLC25A12 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55532854; called by muse, mutect2, varscan2
- SLC26A9 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61602218; called by muse, mutect2, varscan2
- SLC29A3 | c.585G>C p.M195I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as COSV64384896; called by muse, mutect2, varscan2
- SLC2A10 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs898566257, COSV63714309; called by muse, mutect2, varscan2
- SLC36A3 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs867966840, COSV58856585; called by muse, mutect2
- SLC6A15 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99880789; called by muse, mutect2, varscan2
- SLC6A18 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.176); catalogued as COSV57250785; called by muse, mutect2, varscan2
- SLC7A6 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV54718541; called by muse, mutect2, varscan2
- SLCO1B1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV57009976; called by muse, mutect2, varscan2
- SLTM | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51053912; called by muse, mutect2, varscan2
- SMAD3 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59283049; called by muse, mutect2, varscan2
- SMARCB1 | c.972G>T p.R324S (on ENST00000263121; = p.R370S on NM_003073.5) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51954626; called by muse, mutect2, varscan2
- SMC4 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs747478933, COSV59087049; called by muse, mutect2, varscan2
- SMG5 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV100700718, COSV62434922; called by muse, mutect2
- SOD1 | c.145C>G p.H49D | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54255927; called by muse, mutect2, varscan2
- SON | c.5569C>T p.H1857Y | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs1328817515, COSV51655715; called by muse, mutect2, varscan2
- SORCS3 | c.3070G>C p.D1024H | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63794607; called by muse, mutect2, varscan2
- SPATA2L | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1202448415, COSV57046611; called by muse, mutect2, varscan2
- ST6GAL2 | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 44/186 reads (24%) | PolyPhen possibly damaging (0.47); catalogued as rs1159334068, COSV62416436; called by muse, mutect2, varscan2
- STS | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54267672; called by muse, mutect2, varscan2
- SV2B | c.2032C>G p.R678G | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57699449; called by muse, mutect2, varscan2
- SYNE1 | c.16857G>C p.M5619I (on ENST00000367255 / NM_182961.4; = p.M5548I on NM_033071.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54962090; called by muse, varscan2
- SYNE1 | c.5296G>C p.E1766Q (on ENST00000367255 / NM_182961.4; = p.E1773Q on NM_033071.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV54910137, COSV54962145; called by muse, mutect2, varscan2
- SYNE2 | c.8245G>A p.E2749K | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV59947795; called by muse, mutect2, varscan2
- TAF1B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV55155115, COSV55155524; called by muse, mutect2, varscan2
- TAF4 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV53336935, COSV53339465; called by muse, mutect2, varscan2
- TARDBP | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs1433662988, COSV53569642; called by muse, mutect2, varscan2
- TBC1D10A | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV53163919, COSV53164864; called by muse, mutect2, varscan2
- TBXAS1 | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54944027; called by muse, mutect2, varscan2
- TCHH | c.4454G>C p.R1485T | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs972903925, COSV64274236, COSV64275831; called by muse, mutect2, varscan2
- TDP1 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV59642953; called by muse, mutect2, varscan2
- TERF2IP | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV55613206; called by muse, mutect2, varscan2
- TLR8 | c.1089C>G p.F363L (on ENST00000218032 / NM_138636.5; = p.F381L on NM_016610.4) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104373384, COSV54317432; called by muse, mutect2, varscan2
- TLR8 | c.1405C>G p.H469D (on ENST00000218032 / NM_138636.5; = p.H487D on NM_016610.4) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); catalogued as COSV54317441; called by muse, mutect2, varscan2
- TMEM89 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56571285; called by muse, mutect2, varscan2
- TMPO | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV54122763; called by muse, mutect2, varscan2
- TNRC6B | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57293770; called by muse, mutect2, varscan2
- TRDMT1 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV58318995; called by muse, mutect2
- TRIB3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV53930985; called by muse, mutect2, varscan2
- TRIP11 | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV50918423; called by muse, mutect2, varscan2
- TSGA13 | c.725C>A p.S242* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV58406941; called by muse, mutect2, varscan2
- TSPAN1 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV64339704; called by muse, mutect2, varscan2
- TTC8 | c.1059C>G p.F353L (on ENST00000338104 / NM_001288781.1; = p.F337L on NM_144596.4) | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM117339, COSV57627302; called by muse, mutect2, varscan2
- TXNDC16 | c.2188C>G p.H730D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55984326, COSV55985306; called by muse, mutect2, varscan2
- UBA3 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV62740287; called by muse, mutect2, varscan2
- UGP2 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100451531, COSV61427984; called by muse, mutect2, varscan2
- UGT3A1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs752166325, COSV57097414; called by muse, mutect2, varscan2
- USF3 | c.4154C>T p.S1385L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.475); catalogued as COSV57071904; called by muse, mutect2, varscan2
- USP4 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV55536392; called by muse, mutect2, varscan2
- USP4 | c.519delinsTT p.N174* | Frame Shift Ins (INS) | VAF 45/232 reads (19%) | catalogued as COSV55536411; called by pindel, varscan2*
- USP4 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); catalogued as COSV55535900; called by muse, varscan2
- USP9Y | c.3206G>T p.G1069V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV59099278; called by muse, mutect2, varscan2
- UTP20 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV55375742; called by muse, mutect2, varscan2
- UTP20 | c.6963G>C p.E2321D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55375750, COSV99881263; called by muse, mutect2, varscan2
- UTP25 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71965889; called by muse, mutect2, varscan2
- VEGFD | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52909462; called by muse, mutect2, varscan2
- WDR36 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV72411103; called by muse, mutect2, varscan2
- XPO4 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55006624, COSV55013763; called by muse, mutect2, varscan2
- XPO5 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 27/141 reads (19%) | catalogued as rs761776637; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2702G>C p.R901T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.076); catalogued as COSV60156511; called by muse, mutect2, varscan2
- ZMYM4 | c.4618G>C p.E1540Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV58909486; called by muse, mutect2, varscan2
- ZNF394 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100529768, COSV61793780; called by muse, varscan2
- ZNF479 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV58637824; called by muse, mutect2, varscan2
- ZNF547 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV56580248; called by muse, mutect2, varscan2
- ZNF549 | c.482G>A p.R161K (on ENST00000376233 / NM_001199295.2; = p.R148K on NM_153263.2) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.037); catalogued as COSV53724832, COSV53727114; called by muse, mutect2, varscan2
- ZNF555 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV62073085; called by muse, mutect2, varscan2
- ZNF567 | c.1460G>C p.R487T (on ENST00000536254 / NM_001322913.1; = p.R456T on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV62445031; called by muse, mutect2, varscan2
- ZNF672 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60637378; called by muse, mutect2, varscan2
- ZNF777 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as COSV56097230, COSV99925296; called by muse, mutect2, varscan2
- ZZEF1 | c.2772G>A p.M924I | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs531018809, COSV67557121; called by muse, mutect2, varscan2
- ZZEF1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1433127974, COSV56800614; called by muse, mutect2, varscan2
- ABCA6 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ACIN1 | c.3533C>G p.S1178* | Nonsense Mutation (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- APBB3 | c.766G>T p.E256* (on ENST00000357560 / NM_133173.2; = p.E263* on NM_006051.3) | Nonsense Mutation (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- ARID1A | c.2457_2484delinsAAT p.N820Mfs*5 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by pindel, varscan2*
- ARID4A | c.3011C>G p.S1004* | Nonsense Mutation (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2, varscan2
- BAIAP2 | c.216C>A p.L72= | Splice Region (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- CASC3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 70/173 reads (40%) | called by muse, varscan2
- CETN2 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | called by muse, varscan2
- CHD1 | c.3074C>G p.S1025* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- CSDE1 | c.2173C>T p.Q725* (on ENST00000358528 / NM_001007553.3; = p.Q694* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- FRMD4B | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- FRY | c.5645C>A p.S1882* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- GOLGA2 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- GTF2I | c.2965C>G p.Q989E (on ENST00000573035 / NM_032999.4; = p.Q948E on NM_001518.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.585); called by mutect2, varscan2
- HIPK3 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- HMG20A | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- HSP90AA1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- LAMA5 | c.5522C>A p.S1841* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- NBPF11 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- NOTCH3 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR1H2 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- NTRK3 | c.1430C>G p.S477* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- OBI1 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 77/233 reads (33%) | called by muse, mutect2, varscan2
- OR5H1 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIP4K2B | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PITPNM3 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- PLPP1 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- PRRX1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- RANBP2 | c.6788C>G p.S2263* | Nonsense Mutation (SNP) | VAF 51/370 reads (14%) | called by muse, mutect2, varscan2
- RBP3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RICTOR | c.3112G>T p.E1038* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by mutect2, varscan2
- SUPT5H | c.1943del p.G648Afs*7 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- SYMPK | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- TNRC6B | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2563G>A p.E855K (on ENST00000343537 / NM_001031685.3; = p.E726K on NM_005426.2) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- USPL1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- ZNF587 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ZZZ3 | c.2352C>G p.I784M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM11 | c.663G>C p.L221= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV52345676; called by muse, mutect2
- ADCY1 | c.2577C>G p.L859= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV52033454; called by muse, mutect2, varscan2
- AKAP13 | c.150C>T p.V50= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV63454490; called by muse, mutect2, varscan2
- ALDH1A1 | c.552G>C p.L184= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV52790763; called by muse, mutect2, varscan2
- ANGPTL4 | c.957C>G p.P319= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56844706; called by muse, mutect2, varscan2
- ANPEP | c.870G>A p.V290= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as COSV55590971; called by muse, mutect2, varscan2
- ASGR2 | c.498C>T p.L166= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1337379240, COSV54689990, COSV99642870; called by muse, mutect2, varscan2
- ATIC | c.123C>T p.L41= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52692748; called by muse, mutect2, varscan2
- ATP1A2 | c.1071G>A p.K357= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV63403466; called by muse, mutect2, varscan2
- ATP2B4 | c.1821G>A p.R607= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV58176742; called by muse, mutect2, varscan2
- ATP6V1B1 | c.753C>T p.V251= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV52269086; called by muse, mutect2, varscan2
- BCAN | c.522G>A p.G174= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs769279117, COSV61256534; called by muse, mutect2, varscan2
- BCL9 | c.2601G>A p.T867= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs370283874; called by muse, mutect2, varscan2
- BRAT1 | c.1401G>C p.L467= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.1188G>A p.L396= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60798491; called by muse, mutect2, varscan2
- CCDC88A | c.249G>A p.V83= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV55060275; called by muse, mutect2, varscan2
- COL20A1 | c.255G>C p.L85= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58915439; called by muse, mutect2, varscan2
- DLEC1 | c.2241G>A p.V747= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs1467349134, COSV57298615; called by muse, mutect2, varscan2
- DNAH5 | c.13269C>T p.I4423= | Silent (SNP) | VAF 88/325 reads (27%) | catalogued as rs769984486, COSV54219285; called by muse, mutect2, varscan2
- DZIP1L | c.450C>A p.I150= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59520287; called by muse, mutect2, varscan2
- EHMT1 | c.3762C>T p.F1254= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1224603807, COSV66044703; called by muse, mutect2, varscan2
- FAAP100 | c.921G>A p.V307= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV59884949; called by muse, mutect2, varscan2
- FMO5 | c.1038C>G p.V346= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV54205822; called by muse, mutect2
- GJB3 | c.228C>T p.L76= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV64904527; called by muse, mutect2, varscan2
- GPR78 | c.213G>A p.R71= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV66762948; called by muse, mutect2
- GTF2F1 | c.45C>T p.V15= | Silent (SNP) | VAF 56/284 reads (20%) | catalogued as COSV66725610; called by muse, mutect2, varscan2
- HAUS5 | c.585G>T p.R195= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV52547582; called by muse, mutect2, varscan2
- HGF | c.1305G>C p.L435= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV55948213; called by muse, mutect2
- HPSE2 | c.1353G>C p.L451= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV65187477; called by muse, mutect2, varscan2
- INF2 | c.873C>G p.L291= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV53031926, COSV53033518; called by muse, mutect2, varscan2
- INF2 | c.1614C>A p.I538= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53031939; called by muse, mutect2, varscan2
- INPP5A | c.138G>A p.P46= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs375941297; called by mutect2, varscan2
- INPP5D | c.1830G>A p.Q610= (on ENST00000445964 / NM_001017915.3; = p.Q609= on NM_005541.5) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV64036616; called by muse, mutect2, varscan2
- INPP5E | c.1434C>T p.F478= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV65496174; called by muse, mutect2, varscan2
- INTS3 | c.267C>A p.I89= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as COSV59676874; called by muse, mutect2
- ITGAX | c.2907C>T p.I969= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs751025994, COSV51644873; called by muse, mutect2, varscan2
- JADE2 | c.2211G>A p.E737= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV50914510, COSV50924249; called by muse, mutect2, varscan2
- KDM1A | c.1194C>T p.F398= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV63087577; called by muse, mutect2, varscan2
- KRT76 | c.1212C>G p.L404= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as COSV60119938; called by muse, mutect2, varscan2
- KRT80 | c.657C>A p.I219= | Silent (SNP) | VAF 41/237 reads (17%) | catalogued as COSV57548664; called by muse, mutect2, varscan2
- LRRC37A3 | c.4803C>G p.L1601= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100140825, COSV58537081; called by muse, mutect2
- LRRTM3 | c.696G>A p.Q232= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV63664369; called by muse, mutect2, varscan2
- MC4R | c.750G>A p.L250= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV55351876, COSV55352609; called by muse, mutect2, varscan2
- MLYCD | c.1317G>T p.V439= | Silent (SNP) | VAF 153/243 reads (63%) | catalogued as COSV52304964, COSV99299271; called by muse, mutect2, varscan2
- MYCBPAP | c.2223C>T p.L741= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as COSV60406930; called by muse, mutect2, varscan2
- MYH3 | c.3960G>A p.L1320= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV56863708; called by muse, mutect2, varscan2
- MYT1L | c.1719G>C p.P573= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs776330906, COSV67717937, COSV67733415; called by muse, mutect2, varscan2
- NAV3 | c.1677G>A p.G559= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV57075222; called by muse, mutect2, varscan2
- NLRC4 | c.2550G>T p.L850= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV61592286, COSV61592536; called by muse, mutect2, varscan2
- NWD1 | c.672C>G p.L224= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV60337617, COSV60341216; called by muse, mutect2, varscan2
- OGDHL | c.102C>T p.S34= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs755135947, COSV65101977, COSV65104601; called by muse, mutect2, varscan2
- OR5M8 | c.633C>T p.F211= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV59116502; called by muse, mutect2, varscan2
- OR6K6 | c.294G>A p.E98= (on ENST00000368144; = p.E74= on NM_001005184.1) | Silent (SNP) | VAF 68/282 reads (24%) | catalogued as rs1397695749, COSV63743983; called by muse, mutect2, varscan2
- PIGQ | c.387C>T p.I129= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV50312988; called by muse, mutect2, varscan2
- PLEKHM1 | c.2775G>C p.L925= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV69598737; called by muse, mutect2, varscan2
- PRAMEF8 | c.105C>G p.L35= | Silent (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- RANBP2 | c.5673C>A p.I1891= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs534500585, COSV51699170; called by muse, mutect2, varscan2
- RPUSD3 | c.168C>G p.P56= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV67578937; called by mutect2, varscan2
- S1PR3 | c.984C>T p.I328= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV63980455; called by muse, mutect2, varscan2
- SEC24A | c.1878G>A p.L626= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV59746865; called by muse, mutect2, varscan2
- SH3GLB1 | c.876C>A p.I292= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV65279695; called by muse, mutect2, varscan2
- SHANK2 | c.3729C>T p.L1243= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as rs1555153713, COSV53594862, COSV53607585; called by muse, mutect2
- SIK2 | c.2373C>G p.L791= | Silent (SNP) | VAF 164/540 reads (30%) | catalogued as COSV59251762; called by muse, mutect2, varscan2
- SLC14A2 | c.684C>T p.F228= | Silent (SNP) | VAF 135/433 reads (31%) | catalogued as COSV54908316, COSV54915196; called by muse, mutect2, varscan2
- SLC35F1 | c.507G>A p.V169= | Silent (SNP) | VAF 71/476 reads (15%) | catalogued as COSV64502041; called by muse, mutect2, varscan2
- SLC9A2 | c.2040A>G p.L680= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs767723590, COSV52131162; called by muse, mutect2, varscan2
- SOD1 | c.339C>T p.I113= | Silent (SNP) | VAF 28/241 reads (12%) | catalogued as rs1299542356, CM983783, COSV54255447; called by muse, mutect2, varscan2
- SRBD1 | c.1158C>T p.F386= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV55397927; called by muse, mutect2, varscan2
- STOML3 | c.875G>A p.*292= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV101105363; called by muse, mutect2, varscan2
- TBC1D15 | c.1608C>T p.F536= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as COSV59848841; called by muse, mutect2, varscan2
- THAP11 | c.441G>T p.P147= | Silent (SNP) | VAF 46/272 reads (17%) | catalogued as COSV54645785; called by muse, mutect2, varscan2
- TMEM255A | c.882T>C p.Y294= | Silent (SNP) | VAF 95/148 reads (64%) | catalogued as COSV59028879; called by muse, mutect2, varscan2
- TSPEAR | c.828G>A p.P276= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs371022077; called by muse, mutect2, varscan2
- TTC3 | c.507G>C p.L169= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV61289426; called by muse, mutect2, varscan2
- ULK1 | c.2817G>C p.L939= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100416930, COSV58856081; called by muse, mutect2, varscan2
- USP6 | c.1017C>T p.L339= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs1346078320, COSV51480669; called by muse, mutect2, varscan2
- ZBTB20 | c.591G>A p.V197= (on ENST00000474710 / NM_001164342.2; = p.V124= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV61848376; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504523 G>C | 5'Flank (SNP) | VAF 12/41 reads (29%) | called by muse, varscan2
- AP000769.3 | chr11:65504752 G>A | 5'Flank (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504854 G>T | 5'Flank (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505208 G>T | 5'Flank (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505478 G>T | 5'Flank (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505694 G>T | 5'Flank (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506024 G>A | 5'Flank (SNP) | VAF 14/47 reads (30%) | catalogued as rs1282548791; called by muse, mutect2, varscan2
- AP000769.3 | n.32G>T | RNA (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65214244 C>G | 3'Flank (SNP) | VAF 4/19 reads (21%) | catalogued as rs376669253; called by muse, mutect2, varscan2
- GLYATL1 | c.-79G>A | 5'UTR (SNP) | VAF 11/84 reads (13%) | catalogued as COSV55608593; called by muse, mutect2, varscan2
- KIF14 | chr1:200625047 C>G | 5'Flank (SNP) | VAF 7/29 reads (24%) | catalogued as COSV66261338; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28581041 C>A | 3'Flank (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6553C>G | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- ZNF655 | c.136+3365G>A | Intron (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99402135; called by muse, mutect2, varscan2
